Gene-level copy-number profile of tumor specimen TCGA-KO-8404-01A from TCGA case TCGA-KO-8404, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 78.6 years (28,705 days).
Specimen TCGA-KO-8404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.cd6cd7d2-3087-4089-81e5-1378ee50d37b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KO-8404-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1129f85a-d688-423c-bae5-578079f0b11a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 12,404; copy number 2: 37,944; copy number 3: 9,006; copy number 4: 333; copy number 5: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KO-8404-01A-11D-2308-01): tumor purity 0.71, ploidy 1.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:33,338,978–33,366,243, 2 genes: MYL8P, LYPLA2P1.
- chr9:20,999,509–22,455,740, 56 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:132,878,027–132,890,201, 1 gene: SPACA9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–52,659,301, 4 genes, copy number 5 (within-gene range 3–5): AC097522.2, AC097522.1, RNU6-1252P, USP46.
- chr5:149,057,554–151,028,992, 64 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,983. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
